Somatic mutation profile of tumor specimen TCGA-19-2625-01A (aliquot TCGA-19-2625-01A-01W-0922-08) from TCGA case TCGA-19-2625, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 76.5 years (27,930 days).
Specimen TCGA-19-2625-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 38b53bad-c6bb-4b20-9804-08d5daa9dde0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-19-2625-10A (Blood Derived Normal), aliquot TCGA-19-2625-10A-01D-1495-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/74551f2b-cd10-4434-816f-49ab375e930e

The open-access MAF lists 80 somatic variants for this specimen: 67 protein-altering or splice-affecting, 10 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 10, Frame Shift Ins 4, Frame Shift Del 4, Splice Site 2, Intron 2, RNA 1, In Frame Del 1, In Frame Ins 1, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2303_2311dup p.S768_D770dup | In Frame Ins (INS) | VAF 322/670 reads (48%) | hotspot (GDC flag); catalogued as rs397517109; ClinVar: likely pathogenic / drug response; called by mutect2, varscan2
- TP53 | c.713G>A p.C238Y | Missense Mutation (SNP) | VAF 172/675 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882005, CM034930, COSV52661646, COSV52706816, COSV52804264; ClinVar: likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- TP53 | c.614A>G p.Y205C | Missense Mutation (SNP) | VAF 70/191 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057520007, COSV52665440, COSV52677268, COSV52688506; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAM23 | c.2340dup p.K781Qfs*3 | Frame Shift Ins (INS) | VAF 14/126 reads (11%) | catalogued as rs767549806; called by mutect2, varscan2
- AFDN | c.3107A>G p.Y1036C | Missense Mutation (SNP) | VAF 59/223 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60050773; called by muse, mutect2, varscan2
- AP3B1 | c.2131G>A p.D711N | Missense Mutation (SNP) | VAF 21/317 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs374928061; called by muse, mutect2
- ARMC4 | c.1835C>A p.A612E | Missense Mutation (SNP) | VAF 67/122 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59469404; called by muse, mutect2, varscan2
- ATP11C | c.348A>T p.R116S | Missense Mutation (SNP) | VAF 94/240 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59569453; called by muse, mutect2, varscan2
- CAND2 | c.1237T>A p.W413R (on ENST00000456430 / NM_001162499.2; = p.W320R on NM_012298.3) | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV55992454; called by muse, mutect2
- CD3E | c.490C>T p.R164* | Nonsense Mutation (SNP) | VAF 75/227 reads (33%) | catalogued as rs201840561, COSV62345448, COSV62345905; called by muse, mutect2, varscan2
- CDH5 | c.1009G>A p.V337I | Missense Mutation (SNP) | VAF 104/304 reads (34%) | SIFT tolerated (0.96); PolyPhen benign (0.01); catalogued as rs147523967; called by mutect2, varscan2
- CENPF | c.4408G>A p.E1470K | Missense Mutation (SNP) | VAF 72/144 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.124); catalogued as COSV65275112, COSV65277252; called by muse, mutect2, varscan2
- EIF4G3 | c.247dup p.Q83Pfs*70 | Frame Shift Ins (INS) | VAF 10/77 reads (13%) | catalogued as rs755996348; called by mutect2, varscan2
- EP400 | c.2140C>A p.P714T | Missense Mutation (SNP) | VAF 27/164 reads (16%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV57780231; called by muse, mutect2, varscan2
- EPRS1 | c.3446A>G p.N1149S | Missense Mutation (SNP) | VAF 200/421 reads (48%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.928); catalogued as rs372289785; called by muse, mutect2, varscan2
- EZR | c.13A>G p.I5V | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV61455353; called by muse, mutect2, varscan2
- GLYR1 | c.1140dup p.R381Afs*15 | Frame Shift Ins (INS) | VAF 18/64 reads (28%) | catalogued as rs749150409; called by mutect2, varscan2
- GOLGA6B | c.622C>T p.R208W | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as rs778248868, COSV69770668; called by muse, mutect2, varscan2
- GPR15 | c.1008C>G p.H336Q | Missense Mutation (SNP) | VAF 41/207 reads (20%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.829); catalogued as COSV52521027; called by muse, mutect2, varscan2
- GSTA4 | c.145C>T p.H49Y | Missense Mutation (SNP) | VAF 80/190 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs775060558, COSV63955849; called by muse, varscan2
- HSP90AB1 | c.585G>C p.E195D | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV62335741; called by muse, mutect2, varscan2
- INPP5D | c.2785G>A p.V929M (on ENST00000445964 / NM_001017915.3; = p.V928M on NM_005541.5) | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs760843259, COSV64038901; called by muse, mutect2, varscan2
- JMY | c.856T>C p.C286R | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV68661750; called by muse, mutect2, varscan2
- KCNC3 | c.2141C>T p.A714V | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.012); catalogued as rs867151040, COSV65387698; called by muse, mutect2
- KRTAP24-1 | c.562G>A p.V188I | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.019); catalogued as rs200135144, COSV61089693; called by muse, mutect2, varscan2
- MAP3K19 | c.788A>C p.E263A | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV59638825, COSV59640871; called by muse, mutect2, varscan2
- MC3R | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 233/624 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54764546; called by muse, mutect2, varscan2
- MED7 | c.260T>C p.I87T | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs1358020130, COSV53850446, COSV99644181; called by muse, mutect2, varscan2
- MGME1 | c.7A>G p.M3V | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as rs771609402, COSV66624535; called by muse, mutect2, varscan2
- MUC16 | c.19421A>G p.H6474R | Missense Mutation (SNP) | VAF 116/776 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.072); catalogued as COSV67480962; called by muse, mutect2, varscan2
- NPHS2 | c.1082T>C p.L361P | Missense Mutation (SNP) | VAF 69/298 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as CM055460, COSV62636024; called by muse, mutect2, varscan2
- OR1G1 | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 270/1041 reads (26%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.716); catalogued as rs201573244, COSV61030117; called by muse, mutect2, varscan2
- PHF3 | c.3527A>T p.Q1176L | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as COSV50329299; called by muse, mutect2, varscan2
- PLCXD1 | c.947T>C p.L316P | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58205435; called by muse, mutect2, varscan2
- PPP1R7 | c.760C>G p.L254V | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52146116; called by muse, mutect2, varscan2
- PRRG1 | c.401dup p.P135Tfs*3 | Frame Shift Ins (INS) | VAF 36/230 reads (16%) | catalogued as rs781858060, COSV66158042; called by mutect2, varscan2
- PTEN | c.209T>A p.L70H | Missense Mutation (SNP) | VAF 27/41 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1513158, CS982332, COSV64301989, COSV64310663; called by muse, mutect2, varscan2
- REPS1 | c.1604C>T p.S535F (on ENST00000450536 / NM_001286611.2; = p.S534F on NM_031922.4) | Missense Mutation (SNP) | VAF 20/260 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs773092545; called by muse, mutect2
- SCN7A | c.4681G>T p.A1561S | Missense Mutation (SNP) | VAF 80/237 reads (34%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.979); catalogued as COSV69273477; called by muse, mutect2, varscan2
- SLAMF6 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 168/284 reads (59%) | SIFT tolerated (0.15); PolyPhen benign (0.333); catalogued as COSV63587748; called by muse, mutect2, varscan2
- SPOCD1 | c.868G>A p.A290T | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs555926182, COSV57095318, COSV57097256; called by muse, mutect2, varscan2
- TBC1D2 | c.315C>G p.D105E | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59787143; called by muse, mutect2, varscan2
- TBX22 | c.601C>G p.L201V | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64787003, COSV64787147; called by muse, mutect2, varscan2
- TGFA | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs782074408, COSV54913414, COSV54913742; called by muse, mutect2, varscan2
- THNSL2 | c.80G>A p.G27E | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59083963, COSV59084283; called by muse, mutect2, varscan2
- UNC45B | c.2245C>T p.R749W | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.613); catalogued as rs746256786; called by muse, mutect2
- ABCC9 | c.1011+1del p.X337_splice | Splice Site (DEL) | VAF 34/96 reads (35%) | called by mutect2, pindel, varscan2
- ALLC | c.563C>G p.T188S | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); called by mutect2, varscan2
- CLCA1 | c.931del p.D312Tfs*15 | Frame Shift Del (DEL) | VAF 155/734 reads (21%) | called by mutect2, pindel, varscan2
- EGR1 | c.121_123del p.L41del | In Frame Del (DEL) | VAF 9/27 reads (33%) | called by pindel, varscan2
- EPB41L4B | c.869G>T p.G290V | Missense Mutation (SNP) | VAF 9/279 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GALNT1 | c.985C>A p.Q329K | Missense Mutation (SNP) | VAF 20/676 reads (3%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.658); called by muse, mutect2
- HJURP | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- IGKV1D-17 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 74/642 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.57); called by muse, mutect2
- ITIH1 | c.1976C>A p.T659N | Missense Mutation (SNP) | VAF 56/174 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.015); called by mutect2, varscan2
- LDLR | c.446G>T p.G149V | Missense Mutation (SNP) | VAF 16/256 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); called by muse, mutect2
- NFATC4 | c.935C>A p.P312H | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.56); called by mutect2, varscan2
- NT5C1A | c.583C>A p.P195T | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.034); called by muse, mutect2
- OSMR | c.2816C>A p.A939E | Missense Mutation (SNP) | VAF 44/1345 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, mutect2
- PKN1 | c.528G>T p.K176N | Missense Mutation (SNP) | VAF 13/143 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PTGDS | c.552T>C p.D184= | Splice Region (SNP) | VAF 74/94 reads (79%) | called by mutect2, varscan2
- PTPN14 | c.2545-1_2546del p.X849_splice | Splice Site (DEL) | VAF 68/283 reads (24%) | called by mutect2, pindel, varscan2
- RB1 | c.492_499del p.L165Dfs*3 | Frame Shift Del (DEL) | VAF 40/91 reads (44%) | called by mutect2, pindel, varscan2
- SLTM | c.1282_1285del p.G428Lfs*2 | Frame Shift Del (DEL) | VAF 38/340 reads (11%) | called by mutect2, pindel
- TRIP10 | c.923C>T p.P308L | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.813); called by muse, mutect2
- VN1R2 | c.1000_1001del p.T334Lfs*9 | Frame Shift Del (DEL) | VAF 68/352 reads (19%) | called by mutect2, pindel, varscan2
- ZNF394 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 19/180 reads (11%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CDH1 | c.2073C>T p.A691= | Silent (SNP) | VAF 74/463 reads (16%) | catalogued as rs536104508; ClinVar: likely benign; called by mutect2, varscan2
- COL6A2 | c.2409C>T p.D803= | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as rs745800327, COSV56011690; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DOCK5 | c.3801C>T p.H1267= | Silent (SNP) | VAF 394/1293 reads (30%) | catalogued as rs755820411, COSV52407390; called by muse, mutect2, varscan2
- IGSF9B | c.2449C>T p.L817= | Silent (SNP) | VAF 9/56 reads (16%) | called by muse, mutect2, varscan2
- LDLR | c.1395T>C p.Y465= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as COSV52944949; called by muse, mutect2
- LRIG1 | c.1122G>A p.T374= | Silent (SNP) | VAF 42/70 reads (60%) | catalogued as rs770308260, COSV56245103; called by muse, mutect2, varscan2
- SGPP1 | c.426C>T p.L142= | Silent (SNP) | VAF 96/139 reads (69%) | catalogued as COSV55975563; called by muse, mutect2, varscan2
- TCTN2 | c.1890G>A p.L630= | Silent (SNP) | VAF 241/348 reads (69%) | called by muse, mutect2, varscan2
- UGT1A1 | c.84G>A p.G28= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV59394402; called by muse, mutect2, varscan2
- WNT10B | c.466C>A p.R156= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV56406016; called by muse, mutect2, varscan2
- ALG13 | c.383+2848C>A | Intron (SNP) | VAF 4/13 reads (31%) | called by muse, mutect2, varscan2
- C1orf220 | n.417G>A | RNA (SNP) | VAF 17/25 reads (68%) | catalogued as rs1246525815; called by muse, mutect2, varscan2
- THRA | c.1110+89T>G | Intron (SNP) | VAF 19/48 reads (40%) | catalogued as COSV99225664; called by muse, mutect2, varscan2
